Somatic mutation profile of tumor specimen TCGA-LC-A66R-01A (aliquot TCGA-LC-A66R-01A-41D-A30E-08) from TCGA case TCGA-LC-A66R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.8 years (28,793 days).
Specimen TCGA-LC-A66R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64883013-4699-49b1-8d72-dc0f2b8f3d68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LC-A66R-10A (Blood Derived Normal), aliquot TCGA-LC-A66R-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e331f990-3eef-4561-a431-ecf5a5b5ce74

The open-access MAF lists 147 somatic variants for this specimen: 107 protein-altering or splice-affecting, 34 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 34, Nonsense Mutation 11, Intron 3, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs759124417, COSV58782650, COSV58783750; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 51/94 reads (54%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV58155258; called by muse, mutect2
- ADAM32 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as COSV65948247; called by muse, mutect2, varscan2
- ADAMTS17 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs753474247, COSV51476592; called by muse, mutect2, varscan2
- AHCY | c.1233G>C p.E411D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV54152910; called by muse, varscan2
- ALPK3 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV51931790; called by muse, mutect2, varscan2
- ANLN | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV56074914; called by muse, mutect2, varscan2
- ARHGDIA | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs1357682654, COSV53906549; called by muse, mutect2, varscan2
- ARHGEF12 | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV63103522; called by muse, mutect2, varscan2
- ARID1A | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 44/149 reads (30%) | catalogued as COSV61387383, COSV61388492; called by muse, varscan2
- BAZ1B | c.1147C>G p.H383D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.01); catalogued as COSV59989945; called by muse, mutect2, varscan2
- BICD2 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.8); PolyPhen probably damaging (1); catalogued as rs200091763, COSV63548495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLOC1S2 | c.131T>A p.M44K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV58395323; called by muse, mutect2, varscan2
- BOD1L1 | c.3352G>T p.E1118* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as COSV99238519; called by muse, mutect2, varscan2
- CAAP1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as COSV61700507, COSV61700686; called by muse, mutect2, varscan2
- CACNA1H | c.4632C>G p.F1544L | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61986931; called by muse, mutect2, varscan2
- CDR2L | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61500810; called by muse, mutect2, varscan2
- CHRNA1 | c.971T>G p.L324R (on ENST00000261007 / NM_001039523.3; = p.L299R on NM_000079.4) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53682411; called by muse, mutect2
- CLEC1A | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59531431; called by muse, mutect2, varscan2
- CNTN6 | c.599A>C p.N200T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV63167367; called by muse, mutect2, varscan2
- COL12A1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764727126, COSV59392637; called by muse, mutect2, varscan2
- COL4A1 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs767374916, COSV65423461; called by muse, mutect2, varscan2
- CTNNA2 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV63552102, COSV63557278; called by muse, mutect2
- CTR9 | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs758762967, COSV63728201, COSV63729779; called by muse, mutect2, varscan2
- CUL9 | c.2348A>G p.E783G | Missense Mutation (SNP) | VAF 41/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52727037; called by muse, mutect2
- CYP2C19 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs56337013, CM983295, COSV64906987; ClinVar: other / drug response; called by muse, mutect2, varscan2
- DCP2 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as COSV66616670; called by muse, mutect2, varscan2
- DLG2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54633321; called by muse, mutect2, varscan2
- DSCAML1 | c.2296G>C p.A766P (on ENST00000321322; = p.A706P on NM_020693.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV58386942; called by muse, mutect2, varscan2
- DUSP11 | c.759G>A p.K253= | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as COSV55594114, COSV55594464; called by muse, mutect2, varscan2
- EDEM1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99849039; called by muse, mutect2, varscan2
- EFCAB12 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs571623088, COSV58175518; called by muse, mutect2, varscan2
- EGFL7 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1207929986, COSV58247321, COSV58248170; called by muse, mutect2, varscan2
- ELF3 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100668613, COSV62837871; called by muse, mutect2, varscan2
- EML4 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100580756, COSV59295784; called by muse, mutect2
- FAM133A | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100220191; called by muse, mutect2, varscan2
- FANCC | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.918); catalogued as COSV56659061; called by muse, mutect2, varscan2
- GALNT14 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61103846; called by muse, mutect2, varscan2
- GINM1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs373801091; called by muse, mutect2, varscan2
- GRIN3A | c.3286G>C p.A1096P | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62452195; called by muse, mutect2, varscan2
- GRM1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51122581; called by muse, mutect2, varscan2
- GTF2B | c.565A>G p.K189E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65136804; called by muse, mutect2, varscan2
- IBTK | c.3922C>G p.L1308V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV60391996; called by muse, mutect2, varscan2
- ITCH | c.731C>G p.S244* (on ENST00000262650 / NM_001257137.3; = p.S203* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV99392072; called by muse, mutect2, varscan2
- ITGB6 | c.1946G>A p.C649Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51792202; called by muse, mutect2, varscan2
- KIF21B | c.776C>G p.S259W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100143526, COSV59755036; called by muse, mutect2, varscan2
- MACF1 | c.18316G>C p.E6106Q (on ENST00000372915; = p.E4151Q on NM_012090.5) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | catalogued as rs774465658, COSV57114431, COSV57117296; called by muse, mutect2, varscan2
- MAML1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.112); catalogued as rs755737129, COSV52984327, COSV52987559; called by muse, mutect2, varscan2
- MAP9 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60904183; called by muse, mutect2, varscan2
- MATR3 | c.510del p.Y171Tfs*54 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as COSV63076571; called by mutect2, pindel, varscan2
- MSH2 | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV51877473; called by muse, mutect2, varscan2
- MTMR14 | c.1622A>G p.D541G | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.411); catalogued as COSV56004141; called by muse, mutect2, varscan2
- MYH4 | c.2953G>C p.E985Q | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV55115490; called by muse, mutect2
- NEB | c.19308G>T p.V6436= | Splice Region (SNP) | VAF 13/55 reads (24%) | catalogued as COSV50920400; called by muse, mutect2, varscan2
- NFS1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs757680256, COSV60764044; called by muse, mutect2, varscan2
- OR1J1 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV52238207; called by muse, mutect2, varscan2
- OR5K1 | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100220883; called by muse, mutect2, varscan2
- PCDHA2 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); catalogued as COSV65366017; called by muse, mutect2, varscan2
- PCDHB16 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV99501273; called by muse, mutect2, varscan2
- PGPEP1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as rs148927470; called by muse, mutect2
- PHLDB1 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV61877376; called by muse, mutect2, varscan2
- PKDCC | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372244846; called by muse, mutect2, varscan2
- PLEKHF2 | c.57A>C p.E19D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100193357; called by muse, mutect2
- PRRC2B | c.2176T>C p.C726R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100621512; called by muse, mutect2
- PTPRD | c.2161G>C p.E721Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as rs1415574662, COSV61932436, COSV61936791; called by muse, mutect2, varscan2
- RAB26 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs780018086, COSV52954309; called by muse, mutect2, varscan2
- RB1 | c.807_808insA p.D270Rfs*6 | Frame Shift Ins (INS) | VAF 19/68 reads (28%) | catalogued as COSV57301602; called by mutect2, pindel, varscan2
- RFX4 | c.974C>G p.S325* (on ENST00000392842 / NM_213594.3; = p.S231* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99985437; called by muse, mutect2, varscan2
- RGS21 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV69881995; called by muse, mutect2
- RIDA | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV54704185, COSV99645326; called by muse, mutect2, varscan2
- RNF181 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100110463, COSV57818668; called by muse, mutect2, varscan2
- RNLS | c.971T>A p.F324Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59292010; called by muse, mutect2, varscan2
- SALL1 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV51755486; called by muse, mutect2, varscan2
- SDCCAG8 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773442925, COSV59406879, COSV59419250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC24A | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV59746509; called by muse, mutect2, varscan2
- SETBP1 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs548105094, COSV56317538; called by muse, mutect2, varscan2
- SHC2 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs754910462, COSV52749988; called by muse, mutect2
- SLCO1B3 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53935064, COSV99680771; called by muse, mutect2, varscan2
- SMC2 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV53956607; called by muse, mutect2, varscan2
- SORL1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52751449, COSV52751945; called by muse, mutect2, varscan2
- SPOP | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV61652698, COSV61653164; called by muse, mutect2, varscan2
- SUPT20H | c.739A>T p.N247Y (on ENST00000350612 / NM_001014286.3; = p.N248Y on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62247339; called by muse, mutect2, varscan2
- SYT10 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 9/150 reads (6%) | catalogued as rs1204055233, COSV57340483; called by muse, mutect2
- TAOK3 | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV66825254, COSV66828720; called by muse, mutect2, varscan2
- TBC1D10A | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53163348, COSV53166104; called by muse, mutect2, varscan2
- TDRD5 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV54240791, COSV54251672; called by muse, mutect2, varscan2
- TM7SF3 | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58001838; called by muse, varscan2
- TM7SF3 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58001846; called by muse, varscan2
- TMEM215 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1204273965, COSV61363297; called by muse, mutect2, varscan2
- TPCN1 | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59233964; called by muse, mutect2, varscan2
- TRIM21 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1216089333, COSV54343484; called by muse, mutect2, varscan2
- TTN | c.65933G>A p.S21978N (on ENST00000591111; = p.S14554N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | PolyPhen possibly damaging (0.526); catalogued as COSV59966546; called by mutect2, varscan2
- TTN | c.38437G>A p.E12813K (on ENST00000591111; = p.E5389K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/176 reads (15%) | PolyPhen possibly damaging (0.814); catalogued as COSV59966566; called by muse, mutect2, varscan2
- TUFM | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs753682714, COSV57948631; called by muse, mutect2, varscan2
- UBA6 | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV59175686; called by muse, mutect2
- WSCD1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs893884983, COSV100496869, COSV58494722; called by muse, mutect2, varscan2
- ZCCHC3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV66643025; called by muse, mutect2, varscan2
- ZCCHC8 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs753378950, COSV60317582; called by muse, mutect2, varscan2
- ZNF207 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV58299279, COSV58299416; called by muse, mutect2, varscan2
- ZNF471 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100340406; called by muse, mutect2, varscan2
- ZNF521 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV64124808, COSV64127235; called by muse, mutect2, varscan2
- ZNF750 | c.1868C>G p.A623G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV53959416, COSV53961042; called by muse, mutect2, varscan2
- ZNF77 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 74/186 reads (40%) | catalogued as COSV100094327; called by muse, mutect2, varscan2
- CES5A | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEK9 | c.2160_2169del p.I721Lfs*5 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- NF2 | c.453dup p.D152* | Frame Shift Ins (INS) | VAF 104/250 reads (42%) | called by mutect2, pindel, varscan2
- ADAM19 | c.2403G>A p.G801= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV57426636, COSV99976339; called by muse, mutect2, varscan2
- AKAP11 | c.3316C>T p.L1106= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs902229460, COSV50294699; called by muse, mutect2, varscan2
- AL645922.1 | c.1785C>G p.V595= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1250878292, COSV54960057; called by muse, mutect2, varscan2
- ARID2 | c.993C>T p.G331= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV57600487; called by muse, mutect2, varscan2
- CCDC158 | c.1608G>A p.L536= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV66355491, COSV66357016; called by muse, mutect2
- CCDC65 | c.411C>T p.L137= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV57195076; called by muse, mutect2, varscan2
- CD1A | c.954G>A p.A318= | Silent (SNP) | VAF 87/211 reads (41%) | catalogued as rs768867270, COSV56861045; called by muse, mutect2, varscan2
- CDR2L | c.225C>T p.H75= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1170314951, COSV61500815; called by muse, mutect2, varscan2
- CLPTM1L | c.1308C>T p.F436= | Silent (SNP) | VAF 58/245 reads (24%) | catalogued as rs202096751, COSV57989930; called by muse, mutect2, varscan2
- CXorf66 | c.28T>C p.L10= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV65169054; called by muse, mutect2, varscan2
- DIDO1 | c.2472G>A p.K824= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV56617692; called by muse, mutect2, varscan2
- FAM111A | c.1044A>G p.K348= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV64655196; called by muse, mutect2, varscan2
- FANCA | c.1440C>T p.L480= | Silent (SNP) | VAF 52/237 reads (22%) | catalogued as rs1401053307, COSV66881053; called by muse, mutect2, varscan2
- H2AC21 | c.324C>G p.V108= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs1275013172, COSV58611702; called by muse, mutect2, varscan2
- JUND | c.909C>G p.L303= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53254518; called by muse, mutect2, varscan2
- MDGA2 | c.1581A>C p.G527= (on ENST00000399232 / NM_001113498.2; = p.G229= on NM_182830.4) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV62085017; called by muse, mutect2, varscan2
- MUC17 | c.8994G>A p.P2998= | Silent (SNP) | VAF 204/615 reads (33%) | catalogued as rs185678447; called by muse, mutect2, varscan2
- NANS | c.375G>A p.L125= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52963404; called by muse, mutect2, varscan2
- NEDD4 | c.2358A>C p.V786= (on ENST00000508342 / NM_001284338.1; = p.V367= on NM_006154.4) | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV59060310; called by muse, mutect2, varscan2
- OR2B2 | c.405C>T p.I135= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV57579320; called by muse, mutect2, varscan2
- OR6C6 | c.93C>T p.L31= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV64455631; called by muse, mutect2, varscan2
- OR8H2 | c.777T>C p.Y259= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs769256002, COSV57943954; called by muse, mutect2, varscan2
- OSBP | c.840C>A p.L280= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV55661631; called by muse, mutect2, varscan2
- PARVG | c.876C>G p.V292= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV63561615; called by muse, mutect2, varscan2
- PLXNA2 | c.4455G>A p.L1485= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as COSV65439205; called by muse, mutect2, varscan2
- RELN | c.10329T>C p.H3443= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV58994116; called by muse, mutect2, varscan2
- ROBO2 | c.3622T>C p.L1208= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV59904526; called by muse, mutect2, varscan2
- RPS6KA4 | c.1497G>T p.R499= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53701800, COSV99589981; called by muse, mutect2, varscan2
- SH3RF2 | c.723C>T p.I241= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV63038182; called by muse, mutect2, varscan2
- STX1A | c.810C>T p.I270= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV56094626; called by muse, mutect2
- TRPM6 | c.4404C>T p.I1468= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV62506288; called by muse, mutect2, varscan2
- VWA8 | c.5643C>T p.F1881= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs779895815, COSV64995026; called by muse, mutect2, varscan2
- WDR7 | c.4149G>A p.R1383= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54350801; called by muse, mutect2, varscan2
- WDR81 | c.4764G>C p.V1588= (on ENST00000409644 / NM_001163809.2; = p.V537= on NM_152348.4) | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV58480499; called by muse, mutect2, varscan2
- CMTM1 | c.81+104A>G | Intron (SNP) | VAF 12/110 reads (11%) | catalogued as COSV50451161; called by muse, mutect2, varscan2
- EPHA6 | c.1895-8894G>T | Intron (SNP) | VAF 18/76 reads (24%) | catalogued as COSV101061008; called by muse, mutect2, varscan2
- FBXW7 | c.502-2595G>A | Intron (SNP) | VAF 13/52 reads (25%) | catalogued as rs34496200; called by muse, mutect2, varscan2
- MIR1323 | n.21G>T | RNA (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- MIR376B | n.79A>G | RNA (SNP) | VAF 5/13 reads (38%) | catalogued as rs1222586068; called by muse, mutect2, varscan2
- TBX2 | chr17:61412730 G>A | 3'Flank (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
